Somatic mutation profile of tumor specimen C3N-00312-01 (aliquot CPT0009040009) from CPTAC case C3N-00312, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 68.8 years (25,123 days).
Specimen C3N-00312-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffb9ebce-fbd3-4df8-8508-05b6346c2349.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00312-31 (Blood Derived Normal), aliquot CPT0009090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38732930-f490-4214-8ad3-9957d83c6417

The open-access MAF lists 87 somatic variants for this specimen: 65 protein-altering or splice-affecting, 13 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 13, Frame Shift Del 7, Splice Site 4, 3'UTR 4, Splice Region 3, Intron 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Ins 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPERG | c.815C>G p.S272C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.723); catalogued as rs1366216301; called by muse, mutect2, varscan2
- CHD7 | c.6499G>A p.V2167I | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs971937875; called by muse, mutect2, varscan2
- DSC1 | c.2407G>A p.V803I | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1218671127, COSV57145820; called by muse, mutect2
- GGA3 | c.1445C>T p.S482F (on ENST00000537686 / NM_138619.4; = p.S449F on NM_014001.5) | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1178473582; called by muse, mutect2, varscan2
- HPS6 | c.629C>G p.P210R | Missense Mutation (SNP) | VAF 143/641 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs753587696; called by muse, mutect2, varscan2
- IFT81 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767705291; called by muse, mutect2, varscan2
- LPAR6 | c.756T>G p.Y252* | Nonsense Mutation (SNP) | VAF 50/186 reads (27%) | catalogued as rs944321155, CM153496; called by muse, mutect2, varscan2
- MAPT | c.1677C>G p.N559K (on ENST00000262410 / NM_001377265.1; = p.N167K on NM_005910.5) | Missense Mutation (SNP) | VAF 80/337 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52242881; called by muse, mutect2, varscan2
- PCLO | c.2974A>G p.K992E | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as rs1246670068; called by muse, mutect2, varscan2
- PHTF1 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 82/339 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.953); catalogued as rs759006715; called by muse, mutect2, varscan2
- PPP1R12C | c.2008C>G p.P670A | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV52383486; called by muse, mutect2, varscan2
- RYR1 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 93/484 reads (19%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.987); catalogued as COSV62108397; called by muse, mutect2, varscan2
- SH3PXD2A | c.1555C>T p.R519W (on ENST00000369774 / NM_001365079.1; = p.R491W on NM_014631.2) | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100280177, COSV60118315; called by muse, mutect2, varscan2
- TCOF1 | c.2659-1G>C p.X887_splice (on ENST00000377797 / NM_001135243.1; = p.X810_splice on NM_000356.4) | Splice Site (SNP) | VAF 96/441 reads (22%) | catalogued as COSV60345624; called by muse, mutect2, varscan2
- YLPM1 | c.4604C>A p.S1535* | Nonsense Mutation (SNP) | VAF 69/218 reads (32%) | catalogued as COSV53119977; called by muse, mutect2, varscan2
- ZNF655 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs774474239, COSV53159970; called by muse, mutect2, varscan2
- ZNF790 | c.694G>T p.G232W | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63213016; called by muse, mutect2, varscan2
- ADCY9 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 88/384 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ASIC2 | c.436T>C p.Y146H | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ATP11B | c.2095G>C p.G699R | Missense Mutation (SNP) | VAF 16/257 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BCAN | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BSN | c.5665C>A p.L1889I | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFAP74 | c.4664_4666del p.P1555del | In Frame Del (DEL) | VAF 11/45 reads (24%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.3749G>A p.G1250D | Missense Mutation (SNP) | VAF 15/379 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2
- COL6A6 | c.4783G>C p.E1595Q | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.741); called by muse, mutect2
- CRYBG1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAI4 | c.1291+2T>A p.X431_splice | Splice Site (SNP) | VAF 34/163 reads (21%) | called by muse, mutect2, varscan2
- DNAJC1 | c.635+2T>C p.X212_splice | Splice Site (SNP) | VAF 32/104 reads (31%) | called by muse, mutect2, varscan2
- DNM2 | c.2443C>A p.P815T (on ENST00000355667 / NM_001005360.3; = p.P811T on NM_004945.3) | Missense Mutation (SNP) | VAF 65/278 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EYA3 | c.1625A>T p.E542V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GAL | c.368C>A p.S123Y | Missense Mutation (SNP) | VAF 70/317 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- GCN1 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 38/147 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRN | c.934-2A>G p.X312_splice | Splice Site (SNP) | VAF 84/373 reads (23%) | called by muse, mutect2, varscan2
- HCN4 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- HMCN1 | c.9224C>A p.T3075N | Missense Mutation (SNP) | VAF 89/415 reads (21%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- HSPA8 | c.1677A>T p.Q559H | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- IGKV1-12 | c.257del p.G86Afs*? | Frame Shift Del (DEL) | VAF 30/265 reads (11%) | called by mutect2, varscan2
- ITPRID2 | c.332del p.S111Ifs*44 | Frame Shift Del (DEL) | VAF 25/173 reads (14%) | called by mutect2, pindel, varscan2
- KCNC2 | c.1660C>A p.P554T | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- LHX6 | c.253-4C>A | Splice Region (SNP) | VAF 30/140 reads (21%) | called by muse, mutect2, varscan2
- LILRB2 | c.1615A>G p.T539A | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- LRP2 | c.2873T>G p.L958R | Missense Mutation (SNP) | VAF 64/249 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MTRF1L | c.188A>C p.E63A | Missense Mutation (SNP) | VAF 143/541 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MYO7A | c.2272T>G p.F758V | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- NBPF14 | c.7948C>G p.L2650V | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLGN2 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 77/341 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NR2C1 | c.89A>T p.Q30L | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSCN | c.9382T>C p.W3128R | Missense Mutation (SNP) | VAF 70/340 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2L3 | c.826T>G p.F276V | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- OR4Q2 | c.166A>G p.N56D | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- PBRM1 | c.3755del p.N1252Mfs*17 (on ENST00000296302 / NM_001366071.2; = p.N1227Mfs*17 on NM_018313.5) | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | called by mutect2, pindel, varscan2
- PPP2CA | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 39/195 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A12 | c.853G>C p.V285L | Missense Mutation (SNP) | VAF 52/323 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- SORBS2 | c.286G>A p.D96N (on ENST00000284776 / NM_021069.5; = p.D142N on NM_003603.6) | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STAT6 | c.1097A>G p.K366R | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- TMEM108 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- TRGV8 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TTLL7 | c.1861_1862delinsA p.F621Ifs*6 | Frame Shift Del (DEL) | VAF 47/369 reads (13%) | called by pindel, varscan2*
- UBE2D3 | c.27A>G p.E9= | Splice Region (SNP) | VAF 42/222 reads (19%) | called by muse, mutect2, varscan2
- UNC13B | c.1215G>A p.G405= | Splice Region (SNP) | VAF 26/112 reads (23%) | called by muse, mutect2, varscan2
- USH2A | c.15174del p.L5059Cfs*3 | Frame Shift Del (DEL) | VAF 68/303 reads (22%) | called by mutect2, pindel, varscan2
- VHL | c.402dup p.L135Ifs*9 | Frame Shift Ins (INS) | VAF 77/280 reads (28%) | called by mutect2, pindel, varscan2
- WDR54 | c.1003_1004del p.*335Rfs*? | Frame Shift Del (DEL) | VAF 27/164 reads (16%) | called by pindel, varscan2
- ZNF19 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ZNF649 | c.1119del p.F374Lfs*88 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- ADH4 | c.537A>C p.G179= | Silent (SNP) | VAF 40/175 reads (23%) | called by muse, mutect2, varscan2
- BRD3 | c.1161C>T p.C387= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as rs1185563179, COSV100325348; called by muse, mutect2, varscan2
- CALB2 | c.516C>T p.G172= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- CDK13 | c.1035A>T p.G345= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- DDX17 | c.1581A>G p.L527= | Silent (SNP) | VAF 137/514 reads (27%) | catalogued as rs369638680; called by muse, mutect2, varscan2
- DST | c.10587A>G p.V3529= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs1292771928; called by muse, mutect2, varscan2
- EXOSC9 | c.468C>G p.A156= | Silent (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- FBLN7 | c.930C>T p.Y310= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs148395500; called by muse, mutect2, varscan2
- ITGA7 | c.3165G>A p.L1055= (on ENST00000555728; = p.L1011= on NM_002206.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 108/484 reads (22%) | catalogued as COSV57696802; called by muse, mutect2, varscan2
- PDE8B | c.792A>G p.K264= | Silent (SNP) | VAF 51/241 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.24864T>C p.A8288= (on ENST00000591111; = p.A7361= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/188 reads (15%) | called by muse, mutect2, varscan2
- TUBB6 | c.270C>T p.F90= | Silent (SNP) | VAF 50/306 reads (16%) | catalogued as rs1324251587, COSV100480964; called by muse, varscan2
- ZFP36 | c.348G>T p.R116= (on ENST00000594442; = p.R110= on NM_003407.5) | Silent (SNP) | VAF 45/228 reads (20%) | called by muse, mutect2, varscan2
- BRCA1 | c.*790G>T | 3'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- BTBD10 | c.101+5043A>C | Intron (SNP) | VAF 23/109 reads (21%) | catalogued as rs1194565378; called by muse, mutect2, varscan2
- COG6 | c.-61G>A | 5'UTR (SNP) | VAF 70/331 reads (21%) | catalogued as rs770910922; called by muse, mutect2, varscan2
- DNPH1 | c.196+192T>C | Intron (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- MFSD4B | c.*415T>A | 3'UTR (SNP) | VAF 51/174 reads (29%) | called by muse, mutect2, varscan2
- PAK1 | c.*115T>A | 3'UTR (SNP) | VAF 31/159 reads (19%) | called by muse, mutect2, varscan2
- POM121L9P | n.773C>T | RNA (SNP) | VAF 50/219 reads (23%) | catalogued as rs1209058384; called by mutect2, varscan2
- SEC31B | c.*11del | 3'UTR (DEL) | VAF 45/187 reads (24%) | called by mutect2, pindel, varscan2
- XIAP | chrX:123860160 C>T | 5'Flank (SNP) | VAF 88/220 reads (40%) | called by muse, mutect2, varscan2
